Somatic mutation profile of tumor specimen MP2PRT-PAREKF-TMP1-A (aliquot MP2PRT-PAREKF-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PAREKF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.8 years (1,758 days).
Specimen MP2PRT-PAREKF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1334217c-d6ee-4b69-8a4e-656e782c1f27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAREKF-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAREKF-NM1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41ab3698-7b13-4ac0-be5f-e0a40b9980ec

The open-access MAF lists 16 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 13, Silent 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4336C>T p.R1446C | Missense Mutation (SNP) | VAF 86/169 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398124146, COSV52113365, COSV52115600, COSV52116725; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CRAMP1 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53531401; called by muse, mutect2, varscan2
- DPP10 | c.1759G>A p.V587I | Missense Mutation (SNP) | VAF 68/158 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs370150768; called by muse, mutect2, varscan2
- FAT2 | c.9763G>A p.V3255M | Missense Mutation (SNP) | VAF 122/375 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as COSV55832340; called by muse, mutect2, varscan2
- GPR20 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 56/552 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.092); catalogued as rs901736337, COSV100897427; called by muse, mutect2, varscan2
- LRRC8E | c.1666G>A p.V556I | Missense Mutation (SNP) | VAF 144/300 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.121); catalogued as rs372027576; called by muse, mutect2, varscan2
- PTPRF | c.871G>A p.V291I | Missense Mutation (SNP) | VAF 38/381 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs765219893, COSV63446059; called by muse, mutect2, varscan2
- CNTNAP3 | c.3638C>T p.A1213V | Missense Mutation (SNP) | VAF 124/412 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, varscan2
- DNAH5 | c.13507A>C p.N4503H | Missense Mutation (SNP) | VAF 52/184 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KLC2 | c.1628G>A p.S543N | Missense Mutation (SNP) | VAF 28/235 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- RIT1 | c.246_247insCCC p.F82_T83insP | In Frame Ins (INS) | VAF 52/193 reads (27%) | called by mutect2, pindel*, varscan2
- SLC22A15 | c.136C>G p.P46A | Missense Mutation (SNP) | VAF 99/278 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STRIP1 | c.2287G>A p.D763N | Missense Mutation (SNP) | VAF 74/252 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ZNF638 | c.1642C>T p.P548S | Missense Mutation (SNP) | VAF 97/184 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- ABCC12 | c.2772G>A p.P924= | Silent (SNP) | VAF 126/263 reads (48%) | catalogued as rs146674868; called by muse, mutect2, varscan2
- TTN | c.36483C>T p.C12161= (on ENST00000591111; = p.C4737= on NM_003319.4) | Silent (SNP) | VAF 67/223 reads (30%) | catalogued as rs749356221; ClinVar: uncertain significance; called by muse, mutect2, varscan2
